Somatic mutation profile of tumor specimen TCGA-EE-A2GE-06A (aliquot TCGA-EE-A2GE-06A-11D-A196-08) from TCGA case TCGA-EE-A2GE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.2 years (19,426 days).
Specimen TCGA-EE-A2GE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77b10455-83c8-4739-be3c-35ac2e54784c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GE-10A (Blood Derived Normal), aliquot TCGA-EE-A2GE-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b03c781-bba9-4a65-ac82-12dc8a231099

The open-access MAF lists 279 somatic variants for this specimen: 176 protein-altering or splice-affecting, 100 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 100, Nonsense Mutation 8, Intron 2, Translation Start Site 1, RNA 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A2 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs1303653650, COSV58698428; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- LAMC1 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV51152730; called by muse, mutect2, varscan2
- ABCA13 | c.10972G>A p.G3658R | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197892471; called by muse, mutect2
- ABCC6 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1249307722, COSV52741921; called by muse, mutect2, varscan2
- ABCC8 | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 29/180 reads (16%) | catalogued as COSV56856224; called by muse, mutect2, varscan2
- AC136428.1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.231); catalogued as COSV101434957; called by muse, mutect2, varscan2
- ACSL5 | c.542C>T p.A181V (on ENST00000354273; = p.A237V on NM_016234.3) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV61132992; called by muse, mutect2, varscan2
- ADAM21 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50789103; called by mutect2, varscan2
- ADAM28 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs139411715; called by muse, mutect2, varscan2
- ADGRV1 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.634); catalogued as COSV67984717, COSV67992872; called by muse, mutect2
- ADGRV1 | c.7988C>T p.S2663F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV67993536; called by muse, mutect2, varscan2
- ADH1B | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1442833744, COSV100520675; called by muse, mutect2, varscan2
- AGL | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as COSV54057339; called by mutect2, varscan2
- AGO4 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV64618345; called by muse, mutect2, varscan2
- ALDOC | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as rs867498954, COSV52024219; called by muse, mutect2, varscan2
- ANXA10 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV63740084; called by muse, mutect2, varscan2
- ARRDC5 | c.64G>A p.E22K (on ENST00000381781; = p.E8K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs769355284, COSV67788233; called by mutect2, varscan2
- ATG14 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV55957754, COSV55957995; called by mutect2, varscan2
- ATG14 | c.1245A>T p.E415D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs749660957, COSV99902668; called by muse, mutect2, varscan2
- ATP8B2 | c.2747C>T p.T916I (on ENST00000672630; = p.T883I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59248283; called by muse, mutect2, varscan2
- BIN2 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV57207952; called by muse, mutect2
- BPIFB6 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs774420213, COSV62754115, COSV62754524; called by mutect2, varscan2
- BRMS1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs747784176, COSV100240164; called by muse, varscan2
- BRWD3 | c.3715C>T p.L1239F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64752521; called by muse, mutect2, varscan2
- BTNL9 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1161773158, COSV59795400; called by mutect2, varscan2
- C1orf105 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as rs769452264, COSV62959797; called by mutect2, varscan2
- C2CD4A | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.51); catalogued as COSV100831039; called by mutect2, varscan2
- C2CD4A | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs756552465, COSV100831040; called by mutect2, varscan2
- CACNB3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99974770; called by muse, mutect2, varscan2
- CACNB3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974771; called by muse, mutect2, varscan2
- CASC3 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99229580; called by muse, mutect2, varscan2
- CASC3 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775380785, COSV99229582; called by muse, mutect2, varscan2
- CBLC | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV54324041, COSV54325367; called by muse, varscan2
- CCDC30 | c.1400T>C p.L467S (on ENST00000340612; = p.L424S on NM_001080850.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.55); catalogued as COSV100501195; called by muse, mutect2, varscan2
- CCDC83 | c.1030G>A p.G344R (on ENST00000342404 / NM_001286159.2; = p.G375R on NM_173556.5) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV54704423; called by muse, varscan2
- CCDC90B | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV52624915; called by mutect2, varscan2
- CD163 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222044619, COSV63136375; called by muse, mutect2, varscan2
- CD19 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV61189451; called by muse, mutect2, varscan2
- CDH18 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs747880884, COSV56953491; called by mutect2, varscan2
- CDH4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs758952645, COSV64670931; called by mutect2, varscan2
- CILP | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753593002, COSV56026231; called by mutect2, varscan2
- CLEC4D | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55230559; called by mutect2, varscan2
- CLPB | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV53632797; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2
- CNTN6 | c.2843G>C p.S948T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV63186362; called by muse, mutect2, varscan2
- COL6A3 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as COSV55104993; called by muse, mutect2, varscan2
- CSMD1 | c.3979G>A p.E1327K (on ENST00000520002; = p.E1326K on NM_033225.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774986931, COSV59371238; called by muse, mutect2, varscan2
- CSMD1 | c.2198G>A p.G733E (on ENST00000520002; = p.G732E on NM_033225.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148719, COSV59276812; called by muse, mutect2, varscan2
- CTNNA2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267599472, COSV58174319; called by muse, mutect2, varscan2
- CYP24A1 | c.1021A>T p.N341Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53774836, COSV53776266; called by muse, varscan2
- CYP3A5 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV56122520; called by muse, mutect2, varscan2
- CYP4F2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV50000659, COSV50001697; called by mutect2, varscan2
- DCDC1 | c.4294G>A p.G1432R (on ENST00000597505 / NM_001367979.1; = p.G539R on NM_020869.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV58002612; called by muse, mutect2, varscan2
- DHX33 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as rs751644376, COSV56580489; called by mutect2, varscan2
- DOP1B | c.5841C>G p.S1947R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67694340, COSV67695497; called by muse, mutect2, varscan2
- DSCAM | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV68652007; called by muse, mutect2, varscan2
- E2F2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1292031937, COSV100674716; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.391); catalogued as rs928418943, COSV62570279; called by muse, mutect2, varscan2
- ELAVL4 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63918685; called by muse, mutect2, varscan2
- EP400 | c.6145C>T p.L2049F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57783953; called by muse, mutect2, varscan2
- F13A1 | c.840G>A p.W280* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV53565567; called by muse, mutect2, varscan2
- FAM186B | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs149783745, COSV57723383; called by muse, mutect2, varscan2
- FBH1 | c.1627C>T p.L543F (on ENST00000362091 / NM_178150.3; = p.L594F on NM_032807.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62984181; called by muse, mutect2, varscan2
- FOXS1 | c.560G>C p.R187P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.741); catalogued as COSV54067921; called by muse, mutect2, varscan2
- FTSJ3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV59563768; called by muse, mutect2, varscan2
- GABRA6 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50890915; called by muse, mutect2, varscan2
- GABRR3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV72084312; called by muse, mutect2, varscan2
- GAS2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV53411598; called by mutect2, varscan2
- GDF5 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs201590447, COSV65503194; called by mutect2, varscan2
- GIMAP8 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56231604; called by muse, mutect2, varscan2
- GIMAP8 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV56233297; called by muse, mutect2, varscan2
- GIP | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.785); catalogued as COSV62467663; called by muse, mutect2, varscan2
- GLCE | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99962195; called by mutect2, varscan2
- GLCE | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.461); catalogued as COSV99962196; called by mutect2, varscan2
- GLOD4 | c.835C>T p.L279F (on ENST00000301328 / NM_001366247.1; = p.L264F on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56754950; called by muse, mutect2
- GRAMD2A | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59034970; called by muse, mutect2, varscan2
- H3-5 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as COSV100461587; called by mutect2, varscan2
- HECTD2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs757057019, COSV99978345; called by muse, mutect2, varscan2
- HERC6 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370223927; called by muse, varscan2
- HIPK2 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs887179043, COSV61231901; called by muse, varscan2
- HNF4G | c.1009C>T p.H337Y (on ENST00000354370 / NM_001330561.2; = p.H384Y on NM_004133.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.37); catalogued as rs369700596, COSV100584855; called by mutect2, varscan2
- IGLV1-51 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759911511; called by mutect2, varscan2
- IKZF3 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV53105947; called by muse, mutect2, varscan2
- KIAA1614 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV62553636; called by muse, mutect2, varscan2
- KIF1B | c.833T>G p.L278W | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55814716; called by muse, mutect2
- KIF9 | c.1792G>A p.E598K (on ENST00000265529 / NM_001377474.1; = p.E533K on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV55522959; called by muse, mutect2, varscan2
- KLK13 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99335220; called by muse, mutect2, varscan2
- KRT20 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV51425945; called by muse, mutect2, varscan2
- LLCFC1 | c.274G>A p.G92S (on ENST00000458732; = p.G61S on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100786954; called by muse, mutect2, varscan2
- LRIG3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.541); catalogued as COSV57867338; called by muse, mutect2, varscan2
- LRP1B | c.5950G>A p.G1984S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67263446; called by muse, mutect2
- MAGEA4 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV52342761; called by muse, mutect2, varscan2
- MAN2A2 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV100847794; called by muse, mutect2
- MAN2A2 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100847796; called by muse, mutect2
- MAP4K2 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53647404; called by muse, mutect2, varscan2
- MCF2 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV58488495; called by muse, mutect2, varscan2
- MDC1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as rs777255794, COSV64526783; called by muse, mutect2, varscan2
- MECOM | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72110994; called by muse, mutect2, varscan2
- MORC1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs867776552, COSV51718259; called by muse, mutect2, varscan2
- MRO | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV56498019; called by muse, mutect2, varscan2
- MRPL28 | c.589C>G p.P197A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs766043650, COSV51741906; called by muse, mutect2, varscan2
- MTSS1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs368960024; called by muse, mutect2, varscan2
- MUC16 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV67459615, COSV67462707; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by mutect2, varscan2
- MYOM2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV50757583; called by muse, mutect2, varscan2
- MYOZ2 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61085948; called by mutect2, varscan2
- NAT10 | c.2015C>T p.T672I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV57665904; called by muse, mutect2, varscan2
- NBEAL1 | c.5710C>T p.P1904S | Missense Mutation (SNP) | VAF 116/376 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV68917071; called by muse, mutect2, varscan2
- NEFM | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV55334521; called by mutect2, varscan2
- NSD3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100388545; called by muse, mutect2, varscan2
- NSD3 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs74585221, COSV100388546; called by muse, mutect2, varscan2
- OR2M5 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100822785, COSV100822882, COSV63546894; called by muse, mutect2, varscan2
- PBRM1 | c.3673C>T p.P1225S (on ENST00000296302 / NM_001366071.2; = p.P1200S on NM_018313.5) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56282584; called by muse, mutect2, varscan2
- PCDHA3 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV63545209; called by muse, mutect2, varscan2
- PCLO | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV61618634; called by muse, mutect2, varscan2
- PCSK9 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56164257; called by muse, varscan2
- PCYT2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58712434; called by mutect2, varscan2
- PHEX | c.1024C>G p.R342G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.897); catalogued as COSV65078177, COSV65079370; called by muse, mutect2, varscan2
- PJVK | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.373); catalogued as COSV64306522; called by muse, varscan2
- PLCB1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1356153164, COSV62064630; called by muse, mutect2, varscan2
- PLCB2 | c.2567A>T p.N856I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99541759; called by muse, varscan2
- PNMA1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs1374537679, COSV54098086; called by muse, mutect2
- POLR2H | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV99201176; called by muse, mutect2
- PPP1R12B | c.2563T>G p.S855A | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.366); catalogued as COSV51788998; called by muse, mutect2
- PPP1R9A | c.3182A>T p.K1061I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56907387; called by mutect2, varscan2
- PRAME | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV67161290, COSV67162375; called by muse, mutect2
- PRDM16 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54605166; called by mutect2, varscan2
- PRDM16 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV54605176; called by mutect2, varscan2
- PSG2 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV68885192; called by muse, mutect2, varscan2
- PTPRB | c.3100A>T p.N1034Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV99716486; called by mutect2, varscan2
- PTPRZ1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV66441044; called by muse, mutect2, varscan2
- RAG2 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57559366; called by muse, mutect2, varscan2
- RASA2 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.957); catalogued as COSV53945287; called by muse, mutect2
- RERG | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57004519; called by muse, mutect2, varscan2
- RGS22 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62666452; called by muse, mutect2, varscan2
- RP1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124306; called by muse, mutect2, varscan2
- RSPH6A | c.1452G>C p.Q484H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574686; called by muse, mutect2, varscan2
- SCAP | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768447765, COSV55560369; called by muse, mutect2, varscan2
- SFMBT1 | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56256854; called by mutect2, varscan2
- SI | c.4450C>T p.R1484C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201282506, COSV52265321; called by mutect2, varscan2
- SIGLEC10 | c.1615+2T>C p.X539_splice | Splice Site (SNP) | VAF 17/82 reads (21%) | catalogued as COSV59485808; called by muse, mutect2, varscan2
- SLC25A52 | c.263G>A p.R88Q (on ENST00000672005; = p.R78Q on NM_001034172.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs865854821, COSV52501584; called by muse, varscan2
- SLC35F3 | c.739C>T p.L247F (on ENST00000366617 / NM_001300845.1; = p.L316F on NM_173508.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs762228997, COSV100784752; called by muse, mutect2, varscan2
- SLC4A4 | c.2970G>A p.M990I (on ENST00000264485 / NM_001098484.3; = p.M946I on NM_003759.4) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV52635141; called by muse, mutect2, varscan2
- SPATA2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753348701, COSV56865497, COSV56868002; called by muse, mutect2, varscan2
- TATDN2 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99813422; called by muse, mutect2, varscan2
- TBC1D31 | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs774327469, COSV54870065; called by muse, mutect2, varscan2
- TEX15 | c.3178A>G p.T1060A (on ENST00000256246; = p.T1443A on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV56352257; called by muse, mutect2, varscan2
- TIE1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV65249930; called by muse, mutect2, varscan2
- TLR3 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV57170063; called by muse, mutect2, varscan2
- TMCO4 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145902797, COSV53876340; called by mutect2, varscan2
- TNS3 | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV60787328; called by muse, mutect2, varscan2
- TOX2 | c.1054C>T p.P352S (on ENST00000358131 / NM_001098798.2; = p.P328S on NM_032883.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV57893599; called by muse, mutect2, varscan2
- TRHR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs751896079, COSV61235589; called by mutect2, varscan2
- TSC22D1 | c.3191C>T p.P1064L (on ENST00000458659 / NM_183422.4; = p.P135L on NM_006022.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as rs748877590, COSV54926452; called by mutect2, varscan2
- TSEN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53190583; called by muse, mutect2, varscan2
- TSSK4 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV55304750; called by mutect2, varscan2
- TTN | c.99032G>A p.R33011K (on ENST00000591111; = p.R25587K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | PolyPhen probably damaging (0.987); catalogued as COSV60284504; called by muse, varscan2
- UNC13A | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV53204871; called by muse, mutect2, varscan2
- UPK3A | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761708746, COSV99343066; called by mutect2, varscan2
- UTRN | c.4168A>G p.T1390A | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV62344753; called by muse, mutect2, varscan2
- VARS2 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV58914349; called by muse, mutect2, varscan2
- ZIM3 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs150510557, COSV54142795; called by muse, mutect2, varscan2
- ZNF43 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV61685538; called by mutect2, varscan2
- ZNF442 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as COSV54422894; called by muse, mutect2, varscan2
- ZNF684 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV65518983; called by muse, mutect2, varscan2
- ZNF85 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60216725; called by muse, mutect2, varscan2
- AREG | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ATRX | c.5365_5368dup p.A1790Vfs*21 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.3551C>T p.T1184I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CWC25 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- IGHV1-46 | c.209T>A p.I70N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IGHV3-16 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.455); called by muse, varscan2
- SRCIN1 | c.3235G>A p.E1079K (on ENST00000621492; = p.E1045K on NM_025248.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TUBGCP5 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2
- ABCC8 | c.3339G>A p.E1113= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs757191246, COSV56856212; ClinVar: likely benign; called by muse, mutect2
- ADAP2 | c.768C>T p.Y256= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100437191; called by muse, varscan2
- ALKBH4 | c.888C>T p.S296= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52961824; called by muse, mutect2, varscan2
- AQP2 | c.375G>A p.T125= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs772192893, COSV52230439; called by mutect2, varscan2
- ATP8B1 | c.27G>T p.T9= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV52179325; called by muse, mutect2, varscan2
- BFAR | c.1173G>A p.Q391= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV55494259; called by muse, mutect2, varscan2
- BNIP5 | c.1242C>T p.V414= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV71325808; called by muse, mutect2, varscan2
- BRAF | c.1917A>C p.T639= (on ENST00000288602 / NM_001374244.1; = p.T599= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV56181274, COSV56211012, COSV56338165, COSV56438362; called by muse, mutect2
- BRINP3 | c.321C>T p.F107= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV66537966, COSV66539549; called by muse, mutect2, varscan2
- BRMS1 | c.153G>A p.E51= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100240172; called by muse, varscan2
- C1QTNF2 | c.627G>A p.R209= (on ENST00000393975; = p.R164= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs1249096200, COSV67433238; called by muse, mutect2, varscan2
- CCDC30 | c.1399T>C p.L467= (on ENST00000340612; = p.L424= on NM_001080850.3) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1441492840, COSV100501193; called by muse, mutect2, varscan2
- CCDC88A | c.2982C>T p.R994= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55068292; called by muse, mutect2, varscan2
- CCNB3 | c.3615C>T p.L1205= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV52069402, COSV52078647; called by muse, mutect2, varscan2
- CDC25A | c.591C>T p.F197= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs1480857925, COSV56772010; called by muse, mutect2, varscan2
- CDH18 | c.630C>T p.V210= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1310964648, COSV56942067; called by muse, mutect2, varscan2
- CFAP126 | c.324G>A p.G108= | Silent (SNP) | VAF 51/138 reads (37%) | catalogued as rs1052773173, COSV61369278; called by muse, mutect2, varscan2
- CFHR4 | c.1701G>A p.R567= (on ENST00000367416 / NM_001201551.2; = p.R321= on NM_006684.5) | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV52234536, COSV99259327; called by muse, mutect2, varscan2
- CKM | c.597C>T p.S199= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1472488136, COSV55534836; called by muse, mutect2, varscan2
- CRNN | c.939C>T p.T313= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as rs1480980147, COSV55123433; called by muse, mutect2
- CYFIP1 | c.609C>T p.S203= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1357339194; called by muse, mutect2
- CYP2C19 | c.1362G>A p.Q454= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV64907136, COSV64909041; called by muse, mutect2, varscan2
- CYP4F12 | c.1266C>T p.I422= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs763995743, COSV61172601; called by mutect2, varscan2
- DNAH10 | c.6358C>T p.L2120= (on ENST00000409039; = p.L2059= on NM_207437.3) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs985835038, COSV68993144, COSV68999816; called by muse, mutect2, varscan2
- DNAJC25 | c.723C>T p.I241= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV57957707; called by muse, mutect2, varscan2
- DRP2 | c.1005C>T p.L335= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV65811550; called by muse, mutect2, varscan2
- DSCAM | c.2619G>A p.E873= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1461724553, COSV68034025; called by muse, mutect2, varscan2
- ELAPOR1 | c.1320G>A p.G440= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV64041081; called by muse, mutect2, varscan2
- ELMO3 | c.1626C>T p.F542= (on ENST00000652269; = p.F489= on NM_024712.5) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV58528132; called by muse, mutect2, varscan2
- ENPP2 | c.795C>T p.T265= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV50031396; called by muse, mutect2, varscan2
- ENTPD4 | c.1284C>T p.F428= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV62270020; called by muse, mutect2, varscan2
- EPHA10 | c.363C>T p.T121= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1187529113, COSV60405158; called by muse, mutect2, varscan2
- FAM83G | c.1581G>A p.L527= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1313436386, COSV58761290; called by muse, mutect2, varscan2
- FRMPD1 | c.135G>A p.R45= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV63383242; called by muse, mutect2, varscan2
- GAA | c.1536C>T p.F512= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs143491365; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- GAB3 | c.1392T>C p.H464= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV65820553; called by muse, varscan2
- GABRG1 | c.732G>A p.R244= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54960348; called by muse, mutect2, varscan2
- GDPD5 | c.1755C>T p.T585= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100409311, COSV61129751; called by muse, varscan2
- GOLGA4 | c.3834T>C p.L1278= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV62713263; called by muse, mutect2, varscan2
- GRM3 | c.1233C>T p.L411= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV64466806; called by muse, mutect2, varscan2
- HECTD2 | c.357C>T p.V119= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99978342; called by muse, mutect2, varscan2
- HIC2 | c.144C>T p.V48= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV68042780, COSV68042976; called by muse, mutect2, varscan2
- HMOX1 | c.804C>T p.L268= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53341058; called by muse, mutect2, varscan2
- HSF1 | c.373C>T p.L125= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs782557719, COSV68822113, COSV68822188; called by muse, mutect2, varscan2
- IFI16 | c.885C>T p.I295= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs149200088; called by muse, mutect2, varscan2
- ITPR3 | c.1119C>T p.T373= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV65413918; called by muse, mutect2, varscan2
- JRK | c.195C>T p.F65= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV70630367; called by muse, mutect2, varscan2
- KCTD3 | c.1245G>A p.Q415= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV52069807; called by muse, mutect2, varscan2
- KDM7A | c.366C>T p.F122= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV50094892; called by muse, mutect2, varscan2
- KLK13 | c.198C>T p.V66= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99335218; called by muse, mutect2, varscan2
- KRT75 | c.444G>A p.E148= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV52874848; called by muse, mutect2, varscan2
- LLCFC1 | c.273G>A p.V91= (on ENST00000458732; = p.V60= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100786952; called by muse, mutect2
- LPIN1 | c.48G>A p.K16= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs757663910, COSV56765622, COSV56769690; called by muse, mutect2, varscan2
- MAPK3 | c.954G>A p.R318= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs747519496, COSV53776006; called by muse, mutect2, varscan2
- MCM3AP | c.1512G>A p.R504= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1397600655, COSV52444528; called by muse, mutect2, varscan2
- MUC16 | c.34089G>A p.R11363= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as COSV67487611; called by muse, mutect2, varscan2
- MUC16 | c.7062C>T p.I2354= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV67487616; called by muse, mutect2, varscan2
- MUC5B | c.2187G>A p.V729= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV71590568; called by muse, mutect2, varscan2
- MYH2 | c.3076C>T p.L1026= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV55446619; called by muse, mutect2, varscan2
- MYH9 | c.2127C>T p.P709= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV53391892; called by muse, varscan2
- NBPF3 | c.717G>A p.Q239= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV59063406; called by muse, mutect2, varscan2
- NCAPD2 | c.978G>A p.L326= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV59701892; called by muse, mutect2, varscan2
- NPC1L1 | c.1173G>A p.R391= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV56926084; called by muse, mutect2, varscan2
- OPRM1 | c.267C>T p.F89= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV57683616; called by muse, mutect2, varscan2
- OR10S1 | c.588C>T p.P196= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs919101809, COSV101602447, COSV101602458; called by muse, mutect2, varscan2
- OR4C12 | c.30C>T p.F10= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs782138512, COSV58860910; called by mutect2, varscan2
- OR4C6 | c.381C>T p.P127= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1436752182, COSV58602479, COSV58605854; called by muse, mutect2, varscan2
- OR5A1 | c.414C>T p.I138= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV57375971; called by mutect2, varscan2
- PCDHGA9 | c.1759C>T p.L587= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99533921; called by muse, varscan2
- PCSK1 | c.894G>A p.G298= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60737144; called by muse, mutect2, varscan2
- PDE10A | c.1125G>A p.R375= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100604955, COSV63050211; called by muse, mutect2, varscan2
- PDE5A | c.564C>T p.F188= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV53351906; called by muse, mutect2, varscan2
- PKHD1 | c.4752C>T p.S1584= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV61891140; called by muse, mutect2, varscan2
- POLR2H | c.372G>A p.R124= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99201177; called by muse, mutect2
- PRH1 | c.90C>T p.L30= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs754663240, COSV70372184; called by mutect2, varscan2
- RIMBP2 | c.2175C>T p.F725= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV55482112; called by muse, mutect2, varscan2
- ROBO2 | c.144G>A p.T48= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV59898272; called by mutect2, varscan2
- RYR1 | c.12144G>A p.V4048= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV62107933; called by muse, mutect2, varscan2
- SAAL1 | c.1401C>T p.F467= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV55516919; called by muse, mutect2, varscan2
- SHANK1 | c.6357C>T p.F2119= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53244442; called by muse, mutect2, varscan2
- SLC35F1 | c.196C>T p.L66= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100837680; called by muse, varscan2
- SLC35F3 | c.738C>T p.A246= (on ENST00000366617 / NM_001300845.1; = p.A315= on NM_173508.4) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs754324150, COSV100784750; called by muse, mutect2, varscan2
- SLC9C1 | c.411C>T p.T137= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV59892107; called by muse, mutect2, varscan2
- TBX18 | c.1482C>T p.P494= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV63737464, COSV63737860; called by muse, mutect2, varscan2
- TBX19 | c.1206G>A p.S402= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs373913285; called by muse, mutect2, varscan2
- TMCC3 | c.1399C>T p.L467= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV54157070; called by muse, mutect2, varscan2
- TMEM18 | c.369G>T p.L123= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55244999; called by muse, mutect2, varscan2
- TNS4 | c.1626C>T p.S542= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1392080256, COSV54187562; called by muse, mutect2, varscan2
- TRMT10B | c.936G>A p.R312= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs752226577, COSV53051194; called by mutect2, varscan2
- TRRAP | c.11265C>T p.V3755= (on ENST00000359863 / NM_001244580.1; = p.V3726= on NM_003496.3) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs779353118, COSV62816667; called by muse, mutect2, varscan2
- TSHZ2 | c.552G>A p.R184= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100295706; called by muse, mutect2, varscan2
- TTN | c.20109C>T p.F6703= (on ENST00000591111; = p.F5776= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV60068749; called by muse, mutect2, varscan2
- UBR4 | c.11001C>T p.V3667= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100920629; called by muse, mutect2
- VARS1 | c.813G>A p.E271= | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as COSV65155622; called by muse, mutect2, varscan2
- VWA3A | c.1122C>T p.S374= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV55394425; called by muse, mutect2, varscan2
- ZC3H3 | c.498C>T p.P166= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52787493; called by muse, mutect2, varscan2
- ZFHX4 | c.7584C>T p.F2528= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV51490022; called by muse, mutect2, varscan2
- ZNF354C | c.924C>T p.A308= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV59608865; called by muse, mutect2, varscan2
- ZNF804B | c.3003G>A p.T1001= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs374394650; called by muse, mutect2, varscan2
- ZSWIM4 | c.2241G>A p.R747= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99584640; called by muse, mutect2, varscan2
- CNOT1 | c.3523-888G>A | Intron (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99799619; called by muse, mutect2, varscan2
- METTL16 | n.981C>T | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- USH1C | c.1285-7573C>T | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as rs1206921951, COSV99139613; called by muse, mutect2
